Somatic mutation profile of tumor specimen BA2781D (aliquot aq-BA2781D) from BEATAML1.0 case 2233, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Undifferentiated leukaemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 68.3 years (24,954 days).
Specimen BA2781D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46729cf0-8229-4ab9-b2ae-a576c4eebd0b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2940D (Solid Tissue Normal), aliquot aq-BA2940D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2e31f31f-e3f8-4508-8730-27833338b07c

The open-access MAF lists 23 somatic variants for this specimen: 16 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 3, Intron 3, Nonsense Mutation 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RUNX1 | c.239G>A p.R80H (on ENST00000344691 / NM_001001890.3; = p.R107H on NM_001754.5) | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1569084106, CM164535, COSV100276589, COSV55867689, COSV55868826; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- C2CD4C | c.727G>A p.A243T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs1436143833, COSV59968137; called by muse, mutect2
- GALNT11 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 30/206 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs780729346, COSV100231794; called by muse, mutect2, varscan2
- KIAA2013 | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.901); catalogued as rs973209308; called by muse, mutect2, varscan2
- LCE1B | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.556); catalogued as rs746468932, COSV100780272; called by muse, mutect2, varscan2
- NRAS | c.176C>A p.A59D | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54738004, COSV54746465; called by muse, mutect2, varscan2
- PKP2 | c.2016G>T p.K672N | Missense Mutation (SNP) | VAF 6/131 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as COSV50729709; called by muse, mutect2
- PLPPR4 | c.1909C>T p.P637S | Missense Mutation (SNP) | VAF 18/88 reads (20%) | SIFT tolerated (0.73); PolyPhen benign (0.031); catalogued as rs1486177221, COSV64567904; called by mutect2, varscan2
- THSD7B | c.2896C>T p.R966* | Nonsense Mutation (SNP) | VAF 27/161 reads (17%) | catalogued as rs754151775, COSV55729368; called by muse, mutect2, varscan2
- TRAV12-1 | c.275T>C p.I92T | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.022); catalogued as rs1244147991; called by muse, mutect2
- IMP3 | c.481G>A p.V161M | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- LAMA1 | c.6356C>A p.A2119D | Missense Mutation (SNP) | VAF 67/271 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PCDHB11 | c.1985T>G p.L662R | Missense Mutation (SNP) | VAF 43/177 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- RMI1 | c.1793C>G p.P598R | Missense Mutation (SNP) | VAF 33/176 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RPL7 | c.218G>C p.R73T | Missense Mutation (SNP) | VAF 30/176 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZBTB49 | c.1268T>C p.F423S | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADGRL3 | c.531G>A p.P177= (on ENST00000506720 / NM_001322402.2; = p.P109= on NM_015236.6) | Silent (SNP) | VAF 32/193 reads (17%) | catalogued as rs754428912; called by muse, mutect2, varscan2
- EPHA1 | c.1707G>A p.R569= | Silent (SNP) | VAF 49/141 reads (35%) | catalogued as rs142999380; called by muse, mutect2, varscan2
- MACF1 | c.10641T>C p.A3547= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as rs1337384234; called by muse, mutect2, varscan2
- CEP120 | c.464-4438G>A | Intron (SNP) | VAF 13/88 reads (15%) | called by muse, mutect2, varscan2
- DTNA | c.1094+1371C>T | Intron (SNP) | VAF 40/298 reads (13%) | catalogued as rs201788110; called by muse, varscan2
- F11 | c.1135+1370C>T | Intron (SNP) | VAF 21/137 reads (15%) | catalogued as rs1036174042; called by muse, mutect2, varscan2
- SNORD116-17 | chr15:25088229 G>C | 3'Flank (SNP) | VAF 6/40 reads (15%) | catalogued as rs188662801; called by muse, mutect2, varscan2
